Gene-level copy-number profile of tumor specimen TCGA-25-1627-01A from TCGA case TCGA-25-1627, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,784 days).
Specimen TCGA-25-1627-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1e7d7cbc-8e20-4f54-971d-09a1264d0401.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1627-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25f1f11d-c410-407c-bdd8-2cc46f611e1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 11,173; copy number 2: 29,770; copy number 3: 12,976; copy number 4: 4,114; copy number 5: 224; copy number 6: 1,089; copy number 7: 262; copy number 8: 125; copy number 9: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1627-01): tumor purity 0.89, ploidy 2.46, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:19,455,418–21,948,772, 12 genes (within-gene range 0–3): AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978.
- chr4:165,361,194–165,498,547, 1 gene (within-gene range 0–1): CPE.
- chr4:165,517,255–165,551,060, 2 genes: SCGB1D5P, NOL8P1.
- chr4:165,664,350–165,665,671, 1 gene: AC080079.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,760 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,508,538–191,228,467, 25 genes, copy number 5 (within-gene range 4–5): AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr6:4,185,479–26,687,964, 408 genes, copy number 6–8 (broad region; genes not listed).
- chr6:57,314,805–57,646,850, 1 gene, copy number 8 (within-gene range 2–8): PRIM2.
- chr6:57,493,855–58,438,364, 14 genes, copy number 8: FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr7:147,080,934–147,704,575, 6 genes, copy number 5: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2.
- chr8:41,261,962–42,555,195, 41 genes, copy number 6: SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr11:68,980,021–70,436,584, 47 genes, copy number 6: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:75,335,092–81,040,236, 110 genes, copy number 5–8 (broad region; genes not listed).
- chr11:81,552,226–89,065,945, 121 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr12:66,767–38,274,549, 861 genes, copy number 5–6 (broad region; genes not listed).
- chr12:70,638,073–74,402,600, 39 genes, copy number 5 (within-gene range 2–5): PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394.
- chr14:22,556,311–23,095,614, 35 genes, copy number 5 (within-gene range 3–5): LINC02332, AC243965.1, DAD1, AC243965.2, ABHD4, OR6J1, AL160314.1, AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1.
- chr18:47,390–515,294, 13 genes, copy number 5: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925.
- chr18:14,337,423–15,330,282, 39 genes, copy number 6–9: CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 8,752. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
